Somatic mutation profile of tumor specimen TARGET-10-PAPEZL-09A (aliquot TARGET-10-PAPEZL-09A-01D) from TARGET case TARGET-10-PAPEZL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,904 days).
Specimen TARGET-10-PAPEZL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fcaf0456-af98-41ba-8390-0c98ac0bdd40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPEZL-10A (Blood Derived Normal), aliquot TARGET-10-PAPEZL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/574fa4ef-e3e5-4a28-bec0-1ebca9179080

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 2, 3'Flank 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL2 | c.1083G>C p.Q361H | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV99592150; called by muse, mutect2, varscan2
- ARHGAP45 | c.1630G>A p.V544M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV104398967; called by muse, mutect2, varscan2
- CLIC2 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 83/139 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV58935904; called by muse, mutect2, varscan2
- CTNND1 | c.2083C>A p.R695S (on ENST00000399050 / NM_001085458.2; = p.R689S on NM_001331.3) | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV62382394; called by muse, mutect2
- KNDC1 | c.3761C>T p.T1254M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769180488, COSV58834403; called by muse, mutect2, varscan2
- NEB | c.3245C>T p.A1082V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.047); catalogued as rs752809792, COSV51417803, COSV51462841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSD2 | c.3374A>G p.D1125G | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56397674; called by muse, mutect2, varscan2
- STPG2 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs200606406; called by mutect2, varscan2
- USP15 | c.2621G>A p.R874H (on ENST00000280377 / NM_001351159.2; = p.R845H on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.717); catalogued as COSV54788718; called by muse, mutect2, varscan2
- AMER1 | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- CNGB1 | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- NIN | c.4197G>T p.Q1399H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.35); called by muse, mutect2
- SHOC1 | c.3001G>T p.A1001S | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- SHROOM3 | c.974C>A p.S325Y | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- SNX5 | c.513+1G>T p.X171_splice | Splice Site (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- CFLAR | c.802C>A p.R268= | Silent (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2, varscan2
- F5 | c.2292C>T p.F764= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs536614946, COSV63124055; called by muse, mutect2, varscan2
- GRIK1 | c.1794-771G>T | Intron (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- IGKV1D-16 | chr2:90100738 ins TCCC | 3'Flank (INS) | VAF 16/26 reads (62%) | called by mutect2, pindel, varscan2
